Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A3FJ, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A3FJ-01A (Primary Tumor).

[page 1 of 3]
ORY MEDICINE PROGRAM

Surgical Pathology Consultation Report

Patient Name:	[REDACTED]	Service:	[REDACTED]	Accession #:	[REDACTED]
MRN:	[REDACTED]	Visit #:	[REDACTED]	Collected:	[REDACTED]
DOB:	[REDACTED]	Location:	[REDACTED]	Received:	[REDACTED]
Gender:	[REDACTED]	Facility:	[REDACTED]	Reported:	[REDACTED]
HCN:	[REDACTED]				
Ordering MD:	[REDACTED]				
Copy To:	[REDACTED]				

Specimen(s) Received

1. Nck: content posterior triangle right
2. Lymph node :Right jugular node stitch marked at apex
3. Lymph node :Apex level 5 node
4. Neck Contentent superior right posterior triangle
5. Parathyroid:Right lower parathyroid/qs
6. Thyroid :Total thyroid stitch at upper pole right lobe
7. Thymus :upper pole right thymus

100-0-3
Carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9 lw 11/22/11

Diagnosis

1. No pathological diagnosis: Lymph nodes, 10 (right posterior triangle) biopsy
2. Metastatic papillary thyroid carcinoma: Lymph nodes, 2 of 12 (right jugular) biopsy
3. No pathological diagnosis: Lymph node (apex, level 5) biopsy
4. No pathological diagnosis: Soft tissue (right superior posterior triangle) biopsy
5. No pathological diagnosis: Parathyroid (right lower) biopsy
6. Multifocal papillary carcinoma, right, dominant 1.0 cm: Thyroid
Metastatic papillary thyroid carcinoma: Lymph nodes, 10, perithyroidal
No pathological diagnosis: Parathyroid, left
- total thyroidectomy specimen
7. No pathological diagnosis: Thymus (right) thymectomy specimen

Synoptic Data

Specimen Type:	Total thyroidectomy & right neck dissection
Tumour Focality:	Multifocal
	Dominant Tumour
Histologic Type:	Papillary carcinoma, classical type
Tumour Site:	Right Lobe
Tumour Size:	Greatest Dimension: 1.0 cm
	Additional Dimensions: 0.8 x 0.6 cm
Capsular Invasion:	Unencapsulated

Case is (check):		

lw 11/22/11

[page 2 of 3]
Surgical Pathology Consultation Report

Extrathyroidal Extension: Locally invasive
Margins: Absent
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L): Margins uninvolved by carcinoma Absent

Secondary Tumour

Histologic Type: Papillary carcinoma, classical type
Tumour Site: Right Lobe
Tumour Size: Greatest Dimension: 0.2 cm
Capsular Invasion: Unencapsulated
Locally invasive
Extrathyroidal Extension: Absent
Margins: Margins uninvolved by carcinoma
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L): Absent

Pathologic Staging (pTNM): pT1: Tumor size 2 cm or less, limited to thyroid
pN1b: Metastases to unilateral, bilateral or contralateral cervical or superior mediastinal lymph nodes
Number of regional lymph nodes examined: 33
Number of regional lymph nodes involved: 12
pMX: Distant metastasis cannot be assessed
Additional Pathologic Findings: Other (specify): additional multifocal papillary microcarcinoma, right

*Pathologic Staging is based on AJCC/UICC TNM,

Electronically verified by:

Clinical History

papillary ca thyroid

Gross Description

1. The specimen labeled with the patient's name and as "content posterior triangle right" consists of a piece of fibroadipose tissue that measures 4 x 1.5 x 1 cm and contains multiple lymph nodes that range from 0.1 x 0.1 x 0.1 to 0.6 x 0.2 x 0.2 cm. Representative sections are submitted.
1A-B multiple nodes
2. The specimen labeled with the patient's name and as "right jugular node stitch marks at apex" consists of a piece of fibroadipose tissue that is oriented with a suture. The specimen measures 5 x 4 x 0.8 cm and contains multiple lymph nodes that range from 0.1 x 0.1 x 0.1 to 2.5 x 1.2 x 0.5 cm. The node at the apex measures 1.6 x 0.9 x 0.6 cm. Representative sections are submitted.
2A apical node bisected
2B-C multiple nodes
2D one node bisected
2E one node bisected
3. The specimen labeled with the patient's name and as "apex level 5 node" consists of 2 pieces of soft tissue that measure 0.5 x 0.3 x 0.1 cm and 0.9 x 0.3 x 0.1 cm.
3A submitted in toto
4. The specimen labeled with the patient's name and as "contents superior right posterior triangle" consists of a piece of fibroadipose tissue that measures 3 x 1 x 0.4 cm. No nodes are identified grossly.
4A sectioned and submitted in toto.
5. The specimen labeled with the patient's name and as "right lower parathyroid" consists of a piece of nodular tissue that measures 0.2 x 0.2 x 0.2 cm. It is frozen for intraoperative consultation.

[page 3 of 3]
5A frozen tissue resubmitted

6. The specimen labeled with the patient's name and as "total thyroid stitch at right pole right lobe" consists of a thyroid gland that is oriented with a suture and weighs 22.5 g. The right lobe measures 4.9 cm SI x 2.3 cm ML x 0.9 cm AP, the left lobe measures 4.2 cm SI x 2.4 cm ML x 0.8 cm AP and the isthmus measures 2.5 cm SI x 1.1 cm ML x 0.4 cm AP. The external surfaces have fibrous adhesions. One cystic nodule in the right mid lateral thyroid measures 0.8 cm in diameter. An inferior piece of soft tissue measures 3 cm SI x 3.5 cm ML x 1.4 cm AP. Multiple lymph nodes identified in the soft tissue range from 0.6 x 0.4 x 0.3 cm to 1 x 0.6 x 0.5 cm; one cystic nodule also identified in the soft tissue measures 1.5 x 1.5 x 1.3 cm and contain yellow fluid. The external surface is painted with silver nitrate. The upper pole of the right lobe contains one well delineated solid nodule that measure 1 cm SI x 0.8 cm ML x 0.6 cm AP. The remainder of the right thyroid tissue shows colloidal nodules: one adjacent to the right upper solid nodule measuring 0.2 x 0.2 x 0.2 cm and one at the right lower pole measuring 0.5 x 0.5 x 0.5 cm. The remaining thyroid is grossly unremarkable. Sections of nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

- 6A-J right lobe, superior to inferior
- 6K isthmus
- 6L-R left lobe, superior to inferior
- 6S cystic nodule from the right lateral mid lobe
- 6T-U multiple node
- 6V solid to cystic nodule from soft tissue

7. The specimen labeled with the patient's name and as "upper pole right thymus" consists of a piece of tan soft tissue that weighs 2.7 g and measures 3.5 x 1.7 x 0.8 cm. It is painted with silver nitrate then breadloafed.

7A-C submitted in toto

Quick Section Diagnosis

5. parathyroid tissue

Source: NCI Genomic Data Commons file a09163ad-824a-45d5-8f03-8d16419a8a8e (TCGA-EM-A3FJ.21F5F753-2DE9-4DB8-9006-768229687C1C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).